Gene-level copy-number profile of tumor specimen TCGA-36-1570-01A from TCGA case TCGA-36-1570, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.2 years (17,956 days).
Specimen TCGA-36-1570-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.e55ec846-0a70-46ec-94c1-8be4a58f82f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-1570-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e942d07-c6d3-47e5-843b-4387c7ad3a86

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 11,610; copy number 2: 36,435; copy number 3: 10,520; copy number 4: 900; copy number 5: 330; copy number 7: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-1570-01): tumor purity 0.95, ploidy 2.01, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:122,739,999–122,793,831, 1 gene (within-gene range 0–2): HSPBAP1.
- chr10:87,751,512–87,971,930, 6 genes (within-gene range 0–1): ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 334 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:54,943,167–55,579,197, 4 genes, copy number 5: AL049555.1, HCRTR2, GFRAL, HMGCLL1.
- chr8:94,637,285–94,707,466, 4 genes, copy number 7 (within-gene range 4–7): AC108860.2, ESRP1, Metazoa_SRP, AC108860.1.
- chr8:98,371,228–98,942,827, 1 gene, copy number 5 (within-gene range 4–5): STK3.
- chr8:98,436,669–100,154,003, 33 genes, copy number 5: AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1, VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K.
- chr19:6,661,253–7,294,414, 24 genes, copy number 5 (within-gene range 3–5): TNFSF14, C3, AC008760.2, GPR108, MIR6791, TRIP10, AC008760.1, SH2D3A, VAV1, ADGRE1, AC020895.2, AC020895.1, Metazoa_SRP, ADGRE4P, AC025278.1, AC025278.2, AC025278.3, MBD3L2B, MBD3L5, MBD3L4, MBD3L2, MBD3L3, ZNF557, INSR.
- chr19:8,778,665–10,339,661, 90 genes, copy number 5 (broad region; genes not listed).
- chr19:11,841,241–14,835,376, 178 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,532. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
